Gene-level copy-number profile of tumor specimen HCM-WCMC-0747-C50-05A from HCMI case HCM-WCMC-0747-C50, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: female; Vital status: Alive; Primary diagnosis: Lobular carcinoma, NOS; Tissue or organ of origin: Breast, NOS; AJCC pathologic stage: Stage IIA; Tumor grade: G3; Age at diagnosis: 43.2 years (15,793 days).
Specimen HCM-WCMC-0747-C50-05A: Sample type: FFPE Scrolls; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 5b48a0e7-769d-4d54-8b49-0867ef02cd59.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator HCM-WCMC-0747-C50-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,236 have no estimate.
https://portal.gdc.cancer.gov/files/3a209f27-14d5-4b97-8726-425571a5f218

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 34; copy number 1: 1,832; copy number 2: 53,512; copy number 3: 2,969; copy number 4: 19; copy number 5: 6; copy number 6: 8; copy number 7: 1; copy number 8: 4; copy number 10: 1; copy number 16: 1.

Homozygous deletions (total copy number 0; autosomes only): 34 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr15:21,328,380–21,752,710, 30 genes: AC060814.4, AC060814.3, LONRF2P4, AC060814.2, CXADRP2, AC060814.1, GRAMD4P6, POTEB3, MIR3118-3, U6, NF1P9, MIR5701-2, AC183088.4, AC183088.2, AC183088.1, LINC02203, AC183088.3, AC135068.6, AC135068.2, AC135068.12, AC135068.11, AC135068.1, AC135068.4, AC135068.5, AC135068.8, AC135068.7, AC135068.9, AC135068.10, AC135068.3, AC134981.1.
- chr16:86,221,420–86,301,303, 2 genes (within-gene range 0–1): LINC01081, Y_RNA.
- chr19:39,328,353–39,342,372, 2 genes: GMFG, AC011445.1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 21 genes in 5 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:998,962–1,000,172, 1 gene, copy number 8: HES4.
- chr9:137,224,635–137,236,555, 3 genes, copy number 5–8: CYSRT1, RNF224, SLC34A3.
- chr9:137,299,631–137,302,271, 1 gene, copy number 7: NRARP.
- chr15:21,843,750–22,095,857, 15 genes, copy number 5–10 (within-gene range 4–45): MIR3118-4, POTEB, RNU6-631P, ZNF519P3, NF1P2, MIR5701-3, OR11J6P, AC134980.1, OR11H3P, AC134980.2, OR11K1P, OR4Q1P, OR4H6P, OR4M2, OR4N4.
- chr21:8,680,538–8,680,934, 1 gene, copy number 16: CR381572.2.

Autosomal genes at a single copy (total copy number 1): 1,832. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
